Somatic mutation profile of tumor specimen TCGA-ET-A40R-01A (aliquot TCGA-ET-A40R-01A-11D-A23M-08) from TCGA case TCGA-ET-A40R, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 24.5 years (8,963 days).
Specimen TCGA-ET-A40R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 65a16a91-4aa5-4699-97ea-3bc3d091dbc8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A40R-10A (Blood Derived Normal), aliquot TCGA-ET-A40R-10A-01D-A23K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae3f1b39-9fe4-4cb5-9004-2a5fe60dcb46

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LMAN2L | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- EPN1 | c.1620C>T p.P540= (on ENST00000270460 / NM_001321263.1; = p.P514= on NM_013333.3) | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as rs537275978, COSV99321582; called by muse, mutect2
